Somatic mutation profile of cancer-model specimen HCM-CSHL-0372-C25-85A (3D Organoid, passage 20; aliquot HCM-CSHL-0372-C25-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-CSHL-0372-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 70.2 years (25,632 days).
Specimen HCM-CSHL-0372-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 20.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aaa63936-2875-48b3-9aa1-bcdb185dc2bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0372-C25-11A (Solid Tissue Normal), aliquot HCM-CSHL-0372-C25-11A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/643d22be-87f6-4601-80c0-d176c3bdd24f

The open-access MAF lists 68 somatic variants for this specimen: 43 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 23, Nonsense Mutation 6, In Frame Del 1, 3'UTR 1, Splice Site 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 434/861 reads (50%) | catalogued as rs137852217, CM090019, COSV57654223; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 337/499 reads (68%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 221/450 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 194/196 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV61683964, COSV61688596, COSV61694890; called by muse, mutect2, varscan2
- AACS | c.251C>A p.S84* | Nonsense Mutation (SNP) | VAF 150/339 reads (44%) | catalogued as rs200646490, COSV55538764; called by muse, mutect2, varscan2
- ADAMTS17 | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 443/947 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs781074609; called by muse, mutect2, varscan2
- ADRM1 | c.395dup p.M133Dfs*21 | Frame Shift Ins (INS) | VAF 247/953 reads (26%) | catalogued as rs1272374701; called by mutect2, pindel, varscan2
- BCAS4 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 545/839 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs111566476; called by muse, mutect2, varscan2
- BCL11A | c.1888G>A p.A630T (on ENST00000335712 / NM_001365609.1; = p.A664T on NM_018014.4) | Missense Mutation (SNP) | VAF 343/705 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100185319, COSV59632438; called by muse, mutect2, varscan2
- CFHR4 | c.1525C>A p.P509T (on ENST00000367416 / NM_001201551.2; = p.P263T on NM_006684.5) | Missense Mutation (SNP) | VAF 128/356 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756854486; called by muse, mutect2, varscan2
- DCHS1 | c.2635C>T p.R879W | Missense Mutation (SNP) | VAF 432/818 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs139750490; called by muse, mutect2, varscan2
- EZHIP | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 322/703 reads (46%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.865); catalogued as rs782146853; called by muse, mutect2, varscan2
- FICD | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 322/700 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs756414496; called by muse, mutect2, varscan2
- FMN2 | c.425C>G p.T142S | Missense Mutation (SNP) | VAF 368/854 reads (43%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1253960201; called by muse, mutect2, varscan2
- IGF2BP1 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 205/449 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV51735379; called by muse, mutect2, varscan2
- KRTAP12-2 | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 439/925 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.324); catalogued as rs369113881; called by muse, mutect2, varscan2
- MECOM | c.2249G>A p.R750Q (on ENST00000468789 / NM_001105078.4; = p.R938Q on NM_004991.4) | Missense Mutation (SNP) | VAF 206/356 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV52961254; called by muse, mutect2, varscan2
- MMP28 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 361/717 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs761787539; called by muse, mutect2, varscan2
- MUC16 | c.16829G>A p.R5610Q | Missense Mutation (SNP) | VAF 268/481 reads (56%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.199); catalogued as rs761072024, COSV67470593; called by muse, mutect2, varscan2
- MUC5B | c.15224G>A p.C5075Y | Missense Mutation (SNP) | VAF 216/475 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71594418; called by muse, mutect2, varscan2
- NEK4 | c.1913C>T p.A638V | Missense Mutation (SNP) | VAF 191/403 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as rs559285627, COSV51782461; called by muse, mutect2, varscan2
- NSL1 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 141/364 reads (39%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.899); catalogued as COSV65327788; called by muse, mutect2, varscan2
- NUB1 | c.1660G>A p.G554R (on ENST00000568733 / NM_001243351.1; = p.G540R on NM_016118.4) | Missense Mutation (SNP) | VAF 429/810 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs375777780; called by muse, mutect2, varscan2
- OTOG | c.2749G>A p.V917M | Missense Mutation (SNP) | VAF 276/682 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs767006121, COSV100695326; called by muse, mutect2
- PCDHB4 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 228/445 reads (51%) | catalogued as rs946920377; called by muse, mutect2, varscan2
- PHACTR1 | c.164T>C p.I55T | Missense Mutation (SNP) | VAF 56/317 reads (18%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs760163672, COSV60678565; called by muse, mutect2, varscan2
- PTPRS | c.1559C>T p.T520M | Missense Mutation (SNP) | VAF 222/510 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs778260386, COSV53609048; called by muse, mutect2, varscan2
- RNF43 | c.1357G>T p.E453* | Nonsense Mutation (SNP) | VAF 327/647 reads (51%) | catalogued as COSV68460881; called by muse, mutect2, varscan2
- TAOK3 | c.161_163del p.K54del | In Frame Del (DEL) | VAF 108/264 reads (41%) | catalogued as rs765520762; called by pindel, varscan2
- TMEM185B | c.410A>G p.D137G | Missense Mutation (SNP) | VAF 350/692 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as rs918389334; called by muse, mutect2, varscan2
- WAS | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 530/1040 reads (51%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.997); catalogued as rs782666797; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD29 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 64/326 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CCAR2 | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 278/628 reads (44%) | called by muse, mutect2, varscan2
- CCDC82 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 134/336 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- EXT2 | c.153G>T p.E51D (on ENST00000343631; = p.E84D on NM_000401.3) | Missense Mutation (SNP) | VAF 266/498 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by mutect2, varscan2
- FFAR2 | c.620T>A p.L207H | Missense Mutation (SNP) | VAF 323/648 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- HELZ2 | c.6154G>A p.D2052N (on ENST00000467148 / NM_001037335.2; = p.D1483N on NM_033405.3) | Missense Mutation (SNP) | VAF 778/1161 reads (67%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MAP3K4 | c.1734G>T p.W578C | Missense Mutation (SNP) | VAF 168/169 reads (99%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPS15A | c.131_133+1del p.X44_splice | Splice Site (DEL) | VAF 196/370 reads (53%) | called by mutect2, pindel, varscan2
- SCNN1A | c.844T>G p.C282G | Missense Mutation (SNP) | VAF 27/597 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SGO1 | c.1004dup p.Y335* | Nonsense Mutation (INS) | VAF 143/380 reads (38%) | called by mutect2, pindel, varscan2
- TRPV4 | c.1132G>T p.A378S | Missense Mutation (SNP) | VAF 230/447 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- YLPM1 | c.2300G>A p.R767K | Missense Mutation (SNP) | VAF 154/365 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- ACRV1 | c.243C>T p.A81= | Silent (SNP) | VAF 263/534 reads (49%) | catalogued as rs141232180; called by muse, mutect2, varscan2
- ALDH4A1 | c.516C>T p.F172= | Silent (SNP) | VAF 354/354 reads (100%) | catalogued as rs1553154020; called by muse, mutect2, varscan2
- APAF1 | c.1410G>A p.P470= (on ENST00000551964 / NM_181861.2; = p.P459= on NM_001160.3) | Silent (SNP) | VAF 193/381 reads (51%) | catalogued as rs1205113196, COSV59665189, COSV59665422; called by muse, mutect2, varscan2
- BARHL1 | c.774G>A p.P258= | Silent (SNP) | VAF 427/428 reads (100%) | catalogued as rs922543244, COSV99707566; called by muse, mutect2, varscan2
- BHLHE40 | c.396G>A p.G132= | Silent (SNP) | VAF 142/295 reads (48%) | called by muse, mutect2, varscan2
- CACNA1H | c.423C>T p.A141= | Silent (SNP) | VAF 228/510 reads (45%) | catalogued as rs769394588; called by muse, mutect2, varscan2
- CACNA2D3 | c.54C>T p.L18= | Silent (SNP) | VAF 220/486 reads (45%) | called by muse, mutect2, varscan2
- CFAP47 | c.6654G>A p.T2218= | Silent (SNP) | VAF 89/189 reads (47%) | called by muse, mutect2, varscan2
- EPCAM | c.18C>G p.V6= | Silent (SNP) | VAF 320/646 reads (50%) | called by muse, mutect2, varscan2
- FMO3 | c.1029C>A p.I343= | Silent (SNP) | VAF 178/447 reads (40%) | called by muse, mutect2, varscan2
- HSPA1A | c.1746C>T p.D582= | Silent (SNP) | VAF 112/687 reads (16%) | catalogued as rs771552351; called by muse, mutect2, varscan2
- HUWE1 | c.7380C>T p.D2460= | Silent (SNP) | VAF 311/677 reads (46%) | catalogued as COSV53335590; called by muse, mutect2, varscan2
- IQUB | c.1515T>C p.I505= | Silent (SNP) | VAF 224/410 reads (55%) | called by muse, mutect2, varscan2
- ITIH2 | c.834C>T p.D278= | Silent (SNP) | VAF 211/443 reads (48%) | catalogued as rs763511313; called by muse, mutect2, varscan2
- KIF23 | c.1872G>A p.K624= | Silent (SNP) | VAF 125/253 reads (49%) | called by muse, mutect2, varscan2
- NUBP2 | c.483G>A p.T161= | Silent (SNP) | VAF 303/604 reads (50%) | catalogued as rs145452816; called by muse, mutect2, varscan2
- PCDHA10 | c.1968G>A p.P656= | Silent (SNP) | VAF 391/835 reads (47%) | catalogued as COSV56515075; called by muse, mutect2, varscan2
- PHF8 | c.1449C>T p.N483= (on ENST00000357988 / NM_001184896.1; = p.N447= on NM_015107.3) | Silent (SNP) | VAF 259/481 reads (54%) | catalogued as COSV100153793; called by muse, mutect2, varscan2
- RTL1 | c.2517C>T p.S839= | Silent (SNP) | VAF 361/765 reads (47%) | called by muse, mutect2
- SCN11A | c.726C>T p.I242= | Silent (SNP) | VAF 151/320 reads (47%) | catalogued as rs771737794, COSV56573163; called by muse, mutect2, varscan2
- SHOX | c.627C>T p.F209= | Silent (SNP) | VAF 298/646 reads (46%) | called by muse, mutect2, varscan2
- SOX1 | c.474C>T p.G158= | Silent (SNP) | VAF 167/309 reads (54%) | called by muse, mutect2, varscan2
- TM2D2 | c.447C>T p.Y149= (on ENST00000456397 / NM_078473.3; = p.Y106= on NM_031940.4) | Silent (SNP) | VAF 144/333 reads (43%) | called by muse, mutect2, varscan2
- FOXO1 | c.*118_*119insC | 3'UTR (INS) | VAF 109/316 reads (34%) | catalogued as rs943801669; called by mutect2, pindel, varscan2
- NOL4L | c.110-8645C>T | Intron (SNP) | VAF 192/820 reads (23%) | called by muse, mutect2, varscan2
